Gene-level copy-number profile of tumor specimen C3N-03875-01 (profiled together with C3N-03875-02) from CPTAC case C3N-03875, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 68.1 years (24,881 days).
Specimen C3N-03875-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6981b193-b07d-48aa-9a27-d9b0a89b5c25.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03875-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/8bdc96bd-160e-452f-b70a-42437af4bae1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 546; copy number 1: 865; copy number 2: 44,090; copy number 3: 10,267; copy number 4: 1,699; copy number 5: 767; copy number 6: 619; copy number 7: 55; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:257,864–359,681, 2 genes (within-gene range 0–4): AP006222.1, AP006222.2.
- chr1:196,819,731–196,959,622, 4 genes (within-gene range 0–2): CFHR1, BX248415.1, CFHR4, CFHR2.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr8:7,934,412–7,938,770, 1 gene (within-gene range 0–3): DEFB108A.
- chr9:61,581,813–61,627,683, 2 genes: AL935212.3, FAM242D.
- chr12:102,217,318–102,230,533, 2 genes (within-gene range 0–2): RN7SL793P, AC093023.1.
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–3): RPS10P2.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–3): AL138808.1, RNU6-1159P, RNU6-115P.
- chr21:13,038,160–13,067,033, 2 genes: ANKRD30BP2, RNU6-614P.
- chr22:18,855,621–18,858,640, 1 gene (within-gene range 0–8): BCRP7.
- chr22:18,906,028–19,031,242, 10 genes (within-gene range 0–2): DGCR6, AC007326.4, PRODH, AC007326.5, AC007326.2, DGCR5, AC007326.3, DGCR5, AC007326.1, AC000095.2.
- chr22:19,029,524–19,031,242, 1 gene: FAM246C.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,442 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:169,083,499–198,123,232, 574 genes, copy number 5–6 (broad region; genes not listed).
- chr5:44,388,732–44,658,569, 2 genes, copy number 6 (within-gene range 2–6): FGF10-AS1, LINC02224.
- chr7:63,699,390–63,700,441, 1 gene, copy number 5: AC079355.1.
- chr7:74,906,673–75,031,528, 2 genes, copy number 6 (within-gene range 1–6): SPDYE12P, CASTOR2.
- chr7:75,410,322–77,995,171, 73 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr12:12,310–12,357,067, 443 genes, copy number 5 (broad region; genes not listed).
- chr12:66,950,754–68,487,863, 29 genes, copy number 5: AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2.
- chr12:70,243,002–72,186,618, 30 genes, copy number 6 (within-gene range 2–6): CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1.
- chr12:73,648,666–75,209,839, 18 genes, copy number 5: AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2.
- chr13:32,586,452–34,083,310, 21 genes, copy number 5: PDS5B, RNY1P4, AL138820.1, LINC00423, TOMM22P3, KL, STARD13, STARD13-IT1, STARD13-AS, AL627232.1, LINC02344, AL138999.2, AL138999.1, AL139383.1, AL161719.1, AL139081.1, RFC3, RNU5A-4P, AL161891.1, AL160394.2, VDAC1P12.
- chr13:102,589,372–114,337,626, 169 genes, copy number 5 (broad region; genes not listed).
- chr14:63,122,888–66,509,394, 79 genes, copy number 6–7 (within-gene range 1–7) (broad region; genes not listed).
- chr22:18,846,811–18,861,049, 1 gene, copy number 8 (within-gene range 0–8): AC008132.1.

Autosomal genes at a single copy (total copy number 1): 862. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
